Gene-level copy-number profile of tumor specimen TCGA-55-6970-01A from TCGA case TCGA-55-6970, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.8 years (24,773 days).
Specimen TCGA-55-6970-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.934307a3-0d06-4981-847b-25cd5da31a5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6970-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b015f7f2-8a49-4dbe-9ad6-5ad1ee7bea39

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 451; copy number 3: 36,317; copy number 4: 8,613; copy number 5: 3,407; copy number 6: 6,779; copy number 7: 2,659; copy number 8: 788; copy number 9: 806.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6970-01A-11D-1943-01): tumor purity 0.56, ploidy 1.36, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,253 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7–8 (broad region; genes not listed).
- chr2:184,049,467–203,636,016, 306 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 9 (broad region; genes not listed).
- chr8:725,188–1,708,476, 10 genes, copy number 7 (within-gene range 4–7): AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4.
- chr8:111,093,263–145,066,685, 527 genes, copy number 7 (broad region; genes not listed).
- chr19:37,007,857–39,182,816, 96 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
